Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4UP, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4UP-01A (Primary Tumor).

[page 1 of 4]
Neck
and Neck

Clinical Diagnosis & History:

year old female with papillary thyroid carcinoma with positive right upper lobe nodular on FNA and right submandibular LN positive for papillary thyroid carcinoma.

Specimens Submitted:

- 1: Rule out right upper parathyroid (fs)
- 2: Lymph node near the right recurrent nerve
- 3: Right thyroid lobe and isthmus
- 4: Left thyroid lobe and isthmus
- 5: Right neck contents levels 2,3 and 4
- 6: Lowest level 4 lymph nodes, right neck

DIAGNOSIS:

1. Soft tissue, "rule out right upper parathyroid"; biopsy:
- Micrometastatic papillary thyroid carcinoma involving one lymph node (1/1)
- The metastatic lymph node is 3 mm
- The metastatic focus is less than 1 mm
- Extranodal extension not identified

Note: the micrometastatic focus was not present on the original frozen section slide.

2. Lymph node near the right recurrent nerve; biopsy:
- One benign lymph node (0/1)

3. Right thyroid lobe and isthmus:

Part # 3

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.6 cm.

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, nos 673.9

hw
10/27/12

[page 2 of 4]
Tumor Encapsulation:
None Identified

Blood Vessel Invasion:
Not Identified

Extrathyroid Extension:
Not Identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Not Identified

Adenoma(s) (away from the carcinoma):
Not Identified

Non-Neoplastic Thyroid:
Exhibits chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid Glands:
Not identified

Lymph Nodes:
Metastatic papillary thyroid carcinoma involving 1 out of 6 lymph nodes (1/6), lymph node with metastasis is 5 mm in greatest dimension, largest tumor deposit is 2.6 mm. No extranodal extension identified.

4. Left thyroid lobe and isthmus; hemithyroidectomy:
- Chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis
- Four benign lymph nodes (0/4)

5. Right neck contents levels 2,3 and 4:

Part # 5

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 30
Number of lymph nodes with metastatic disease: 3
Size of the largest lymph node involved by tumor: 1.5cm.
Size of the largest metastatic focus : 1.45 cm.
Extranodal extension is not identified
Benign skeletal muscle

6. Lowest level 4 lymph nodes, right neck; excision:
- Seven benign lymph nodes (0/7)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

[page 3 of 4]
1). The specimen is received fresh for frozen section consultation, labeled "rule out right upper parathyroid" and consists of single piece of tissue measuring 0.2 x 0.1 x 0.1 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2). The specimen is received fresh, labeled "lymph node near the right recurrent nerve" and consists of a single pink tan firm lymph node measuring 0.8 x 0.5 x 0.2 cm. The lymph node is entirely submitted.

Summary of sections:
LN - lymph node

3). The specimen is received fresh labeled "right thyroid lobe and isthmus". It consists of a 25.5 g, 7.4 x 3.8 x 2.6 cm thyroid lobe. The surface is purple-pink with an intact capsule. The lobe is inked black posterior and blue anterior. Serial sectioning reveals a 1.6 x 1.5 x 1.1 cm ovoid, tan-white, firm, unencapsulated nodule in the upper pole which abuts the anterior aspect and 0.2 cm from the posterior aspect. The remainder of the cut surface is red-pink, nodular meaty. At the medial aspect are multiple pink-tan, firm lymph nodes ranging from 0.4 to 1.2 cm in greatest dimension. No isthmus is identified. A portion of the specimen is sent for TPS. Representative sections are submitted, including all identifiable lymph nodes.

Summary of sections:
RLN - right lobe nodule
RL - right lobe
LN - lymph nodes

4). The specimen is received fresh labeled "left lobe and isthmus". It consists of a 5.5 x 3.5 x 2.3 cm thyroid lobe with a 4 x 1.8 x 1.6 cm isthmus. The surface is purple-pink with an intact capsule. The lobe is inked black posterior and blue anterior. Serial sectioning reveals red-pink, nodular, meaty cut surfaces with no gross lesions identified. At the medial aspect are two pink-tan, firm lymph nodes measuring 0.7 and 0.9 cm in greatest dimension. Representative sections are submitted, including all identifiable lymph nodes.

Summary of sections:
LL - left lobe
IS - isthmus
LN - lymph node
BLN - bisected lymph node

5). The specimen is received fresh labeled "right neck contents levels 2, 3 and 4". It consists of a 11.5 x 4.4 x 1.5 cm portion of red-pink to yellow-tan, fibroadipose tissue with attached 3 x 1.5 x 0.8 cm portion of skeletal muscle, but no submandibular gland or segment of a major vein. The specimen is sent for lymph node dissection to reveal multiple lymph nodes ranging from 0.2 to 1.5 cm in greatest dimension. All identified lymph nodes and representative sections of the remaining specimen are submitted.

Summary of sections:
M - muscle
LN - lymph nodes
BLN - bisected lymph nodes

[page 4 of 4]
6) The specimen is received fresh, labeled "lowest level 4 lymph nodes-right neck" and consists of multiple pink tan firm lymph nodes ranging from 0.4 to 1.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

Summary of Sections:

Part 1: Rule out right upper parathyroid (fs)

Block	Sect. Site	PCs
1	FSC	2

Part 2: Lymph node near the right recurrent nerve

Block	Sect. Site	PCs
1	LN	1

Part 3: Right thyroid lobe and isthmus

Block	Sect. Site	PCs
3	LN	9
3	RL	3
3	RLN	3

Part 4: Left thyroid lobe and isthmus

Block	Sect. Site	PCs
1	BLN	2
1	IS	1
4	LL	5
1	LN	1

Part 5: Right neck contents levels 2,3 and 4

Block	Sect. Site	PCs
5	BLN	10
6	LN	30
1	M	1

Part 6: Lowest level 4 lymph nodes, right neck

Block	Sect. Site	PCs
2	LN	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Benign lymph node
PERMANENT DIAGNOSIS: see final

Source: NCI Genomic Data Commons file c42d630b-fd80-4dce-9b50-cf3ea1a8e52b (TCGA-DJ-A4UP.54D2F116-9BEF-4B6D-A30C-745481122882.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).